Somatic mutation profile of tumor specimen TARGET-10-PAREKM-09A (aliquot TARGET-10-PAREKM-09A-01D) from TARGET case TARGET-10-PAREKM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,583 days).
Specimen TARGET-10-PAREKM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f466e396-df30-473f-9d1c-8154fe5910ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREKM-10A (Blood Derived Normal), aliquot TARGET-10-PAREKM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bf1e084-ad1c-4cac-949c-f6b5e089a0bb

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>G p.N676K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4307G>A p.S1436N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52119405, COSV52136794; called by muse, mutect2, varscan2
- DCAF4L2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs533225288, COSV60483215; called by muse, mutect2, varscan2
- EPS8L2 | c.1062C>T p.I354= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as rs751072821, COSV59348115; called by muse, mutect2, varscan2
- FEZF2 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51864233, COSV99334542; called by muse, mutect2
- NEO1 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774025786, COSV99982085; called by muse, mutect2, varscan2
- BICC1 | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MICAL1 | c.2305-3C>T | Splice Region (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- TCF4 | c.1163A>G p.D388G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TRPS1 | c.3305A>G p.N1102S (on ENST00000220888 / NM_001330599.2; = p.N1115S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- C4orf54 | c.1209C>T p.F403= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs1447262902; called by muse, mutect2, varscan2
- FHL2 | c.285C>T p.N95= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs374383740, COSV100362842; called by muse, mutect2, varscan2
- PKHD1 | c.6042C>T p.Y2014= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs373208457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RSPH6A | c.789C>T p.P263= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs993721077, COSV99680048; called by muse, mutect2, varscan2
- SLC6A12 | c.783C>T p.P261= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs138339838; called by muse, mutect2, varscan2
- OR10C1 | c.*9C>T | 3'UTR (SNP) | VAF 16/68 reads (24%) | catalogued as rs375398258; called by muse, mutect2
